FM case AD274 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/efdde403-84cb-436c-b30e-d047d6845d24

Male, 28.2 years: diagnosis not reported by GDC; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
